Somatic mutation profile of tumor specimen TCGA-2G-AAM3-01A (aliquot TCGA-2G-AAM3-01A-11D-A435-10) from TCGA case TCGA-2G-AAM3, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AAM3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6005861-a335-452a-82f1-40972c1cea91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAM3-10A (Blood Derived Normal), aliquot TCGA-2G-AAM3-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92ff2645-6b52-40b2-b83b-ea50c77f41a5

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Frame Shift Del 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALKAL1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs929677476; called by muse, mutect2, varscan2
- ARFGEF2 | c.1520G>C p.C507S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV64213877; called by muse, mutect2, varscan2
- BDKRB2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs766976697, COSV60016597; called by muse, mutect2, varscan2
- HERC1 | c.11239A>G p.I3747V | Missense Mutation (SNP) | VAF 85/278 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as rs375304469; called by muse, mutect2, varscan2
- KL | c.2731G>A p.G911R | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777451765, COSV66310398; called by muse, mutect2, varscan2
- PGAP1 | c.137C>G p.P46R | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1482212033; called by muse, varscan2
- XDH | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs148108999, COSV65151698; called by muse, mutect2, varscan2
- ATAD5 | c.1751G>T p.S584I | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CRLF3 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DGLUCY | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- GRID2 | c.331_332del p.A111Hfs*29 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- JARID2 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MIER3 | c.1306G>A p.V436I (on ENST00000381199 / NM_001297599.2; = p.V435I on NM_152622.4) | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SETX | c.6010C>G p.L2004V | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF638 | c.2268_2271del p.N756Kfs*3 | Frame Shift Del (DEL) | VAF 61/254 reads (24%) | called by mutect2, pindel, varscan2
- ATP1A3 | c.2319C>T p.D773= (on ENST00000545399 / NM_001256214.2; = p.D760= on NM_152296.5) | Silent (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- DNAJC27 | c.573A>G p.K191= | Silent (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- IKBKE | c.564G>A p.A188= | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as rs781836498, COSV65624907; called by muse, mutect2
- IRX6 | c.1275G>T p.A425= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV51859570, COSV99306271; called by muse, mutect2, varscan2
- VWF | c.4866C>T p.D1622= | Silent (SNP) | VAF 37/363 reads (10%) | called by muse, mutect2, varscan2
- WDR4 | c.819G>A p.L273= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- ZDHHC17 | c.627G>A p.L209= | Silent (SNP) | VAF 82/292 reads (28%) | called by muse, mutect2, varscan2
- BHMT2 | c.-5G>T | 5'UTR (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99669021; called by muse, mutect2
- DENND1B | c.83-20693C>G | Intron (SNP) | VAF 15/44 reads (34%) | catalogued as COSV52472463; called by muse, mutect2, varscan2
